Somatic mutation profile of tumor specimen TCGA-23-1110-01A (aliquot TCGA-23-1110-01A-01W-0486-08) from TCGA case TCGA-23-1110, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 42.1 years (15,383 days).
Specimen TCGA-23-1110-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cc45512-e2be-440d-9842-1fdb463931bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1110-10A (Blood Derived Normal), aliquot TCGA-23-1110-10A-01D-0428-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bba4e26-ef4a-418e-9a6e-4d6790d84460

The open-access MAF lists 139 somatic variants for this specimen: 107 protein-altering or splice-affecting, 28 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 28, Frame Shift Del 8, Splice Site 6, Nonsense Mutation 4, Nonstop Mutation 2, Frame Shift Ins 2, 5'Flank 1, RNA 1, Intron 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 375/395 reads (95%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.2344G>T p.E782* | Nonsense Mutation (SNP) | VAF 69/240 reads (29%) | catalogued as COSV62323671, COSV62324776; called by muse, mutect2, varscan2
- ADGRB3 | c.4072C>A p.Q1358K | Missense Mutation (SNP) | VAF 161/685 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV53253821; called by muse, mutect2, varscan2
- AGBL1 | c.2169G>C p.E723D | Missense Mutation (SNP) | VAF 757/1676 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.044); catalogued as COSV101224349; called by muse, mutect2, varscan2
- AHNAK | c.15374C>G p.S5125C | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57222869; called by muse, mutect2, varscan2
- ARAP2 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 134/346 reads (39%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); catalogued as COSV100395317; called by muse, mutect2, varscan2
- ARAP2 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 136/345 reads (39%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV100395318; called by muse, mutect2, varscan2
- ATP7B | c.4231C>T p.R1411W | Missense Mutation (SNP) | VAF 272/283 reads (96%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs559705781, COSV54441307; called by muse, mutect2, varscan2
- BIRC3 | c.1607C>G p.T536R | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV54818673; called by muse, mutect2, varscan2
- BOD1L1 | c.4831A>G p.K1611E | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV50031763; called by muse, mutect2, varscan2
- C1orf158 | c.344G>C p.R115P | Missense Mutation (SNP) | VAF 111/599 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV55346313, COSV55347418; called by muse, mutect2, varscan2
- C7 | c.1754A>C p.E585A | Missense Mutation (SNP) | VAF 104/269 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as COSV57477613; called by muse, mutect2, varscan2
- CACNA1S | c.485A>C p.K162T | Missense Mutation (SNP) | VAF 110/580 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV62941938; called by muse, mutect2, varscan2
- CD8A | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs755895247, COSV52156850, COSV52158608; called by muse, mutect2, varscan2
- CDH16 | c.843A>T p.E281D | Missense Mutation (SNP) | VAF 102/154 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55338381; called by muse, mutect2, varscan2
- CDK13 | c.3148G>T p.G1050C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV51703585; called by muse, mutect2, varscan2
- CUX1 | c.1547C>G p.S516C | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1232130649; called by muse, mutect2
- DDX58 | c.1171C>G p.L391V | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV65884082; called by muse, mutect2, varscan2
- DKK2 | c.334C>G p.R112G | Missense Mutation (SNP) | VAF 357/744 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs528677483, COSV53396515, COSV53396966, COSV53400713; called by muse, mutect2, varscan2
- DNASE2B | c.20C>A p.A7E | Missense Mutation (SNP) | VAF 126/327 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.353); catalogued as COSV65743647; called by muse, mutect2, varscan2
- DUOX1 | c.2886C>T p.I962= | Splice Region (SNP) | VAF 30/59 reads (51%) | catalogued as COSV58483505, COSV58484331; called by muse, mutect2, varscan2
- EPB42 | c.1001T>A p.M334K (on ENST00000441366 / NM_001114134.2; = p.M364K on NM_000119.3) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55750792; called by muse, mutect2, varscan2
- EPHX1 | c.184-2A>T p.X62_splice | Splice Site (SNP) | VAF 178/706 reads (25%) | catalogued as COSV55302597; called by muse, mutect2, varscan2
- EZHIP | c.1481C>T p.T494I | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.019); catalogued as COSV57956975; called by muse, mutect2, varscan2
- FARP1 | c.1058A>T p.E353V | Missense Mutation (SNP) | VAF 147/809 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV60343030; called by muse, mutect2, varscan2
- FGA | c.2096T>A p.L699Q | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV57398673; called by muse, mutect2, varscan2
- FOXA2 | c.112A>C p.N38H (on ENST00000377115 / NM_153675.3; = p.N44H on NM_021784.5) | Missense Mutation (SNP) | VAF 122/269 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs1247284954, COSV65796704, COSV65796725; called by muse, mutect2, varscan2
- FRMPD4 | c.2894C>A p.P965Q | Missense Mutation (SNP) | VAF 140/261 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.095); catalogued as COSV66219716; called by muse, mutect2, varscan2
- FSTL5 | c.1599A>T p.K533N | Missense Mutation (SNP) | VAF 72/122 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV60213555; called by muse, mutect2
- GMPR2 | c.883G>C p.V295L (on ENST00000355299 / NM_001351022.2; = p.V313L on NM_016576.5) | Missense Mutation (SNP) | VAF 175/1014 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.057); catalogued as COSV57469689; called by muse, mutect2, varscan2
- GON4L | c.907C>G p.H303D | Missense Mutation (SNP) | VAF 95/381 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV55198805; called by muse, mutect2, varscan2
- GPER1 | c.437T>A p.F146Y | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52469946; called by muse, mutect2, varscan2
- HRC | c.1201A>G p.S401G | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.097); catalogued as rs1387230635, COSV53257715; called by muse, mutect2, varscan2
- IGSF22 | c.811-1G>C p.X271_splice | Splice Site (SNP) | VAF 135/286 reads (47%) | catalogued as COSV60036756; called by muse, mutect2, varscan2
- JMJD1C | c.6923T>A p.V2308E | Missense Mutation (SNP) | VAF 73/370 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59513569, COSV59516897; called by muse, mutect2, varscan2
- KCNA5 | c.630G>A p.M210I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV52907594; called by muse, mutect2, varscan2
- KCNU1 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.178); catalogued as COSV67758268; called by muse, mutect2, varscan2
- KMT2C | c.6301C>G p.P2101A | Missense Mutation (SNP) | VAF 349/594 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV51472911; called by muse, mutect2, varscan2
- KRT35 | c.1319A>C p.N440T | Missense Mutation (SNP) | VAF 82/162 reads (51%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV55843936; called by muse, mutect2, varscan2
- LCE5A | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.484); catalogued as rs761623532, COSV57501139; called by muse, mutect2, varscan2
- LECT2 | c.249C>G p.N83K | Missense Mutation (SNP) | VAF 7/181 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV50847119; called by muse, mutect2
- LPIN1 | c.1961A>G p.Q654R | Missense Mutation (SNP) | VAF 316/425 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV56768195; called by muse, mutect2, varscan2
- LRRC23 | c.683A>C p.H228P | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99145362; called by muse, mutect2
- LRRC6 | c.723C>A p.D241E | Missense Mutation (SNP) | VAF 71/431 reads (16%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs776328128, COSV51545002; called by muse, mutect2, varscan2
- LTF | c.1357G>C p.G453R | Missense Mutation (SNP) | VAF 208/399 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99212197; called by muse, mutect2, varscan2
- MAPKAP1 | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 241/494 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.64); catalogued as COSV56371797; called by muse, mutect2, varscan2
- MBTD1 | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV64503957; called by muse, mutect2, varscan2
- MORC1 | c.223+1G>T p.X75_splice | Splice Site (SNP) | VAF 154/545 reads (28%) | catalogued as COSV51725916; called by muse, mutect2, varscan2
- MOS | c.1041A>T p.*347Cext*? | Nonstop Mutation (SNP) | VAF 9/20 reads (45%) | catalogued as COSV61336726; called by muse, mutect2, varscan2
- MUC17 | c.11951C>A p.S3984Y | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as COSV60296749; called by muse, mutect2, varscan2
- MXRA5 | c.2629C>G p.P877A | Missense Mutation (SNP) | VAF 274/542 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV54243266; called by muse, mutect2, varscan2
- MYO15A | c.7705T>A p.F2569I | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.085); catalogued as COSV52761422, COSV99232000; called by muse, mutect2, varscan2
- MYOM2 | c.3951C>A p.D1317E | Missense Mutation (SNP) | VAF 69/301 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as rs568923144, COSV50741608; called by muse, mutect2, varscan2
- NDUFV3 | c.325T>G p.*109Gext*5 (on ENST00000340344 / NM_001001503.2; = p.*474Gext*5 on NM_021075.4) | Nonstop Mutation (SNP) | VAF 66/303 reads (22%) | catalogued as COSV61088167; called by muse, mutect2, varscan2
- NR6A1 | c.184A>T p.I62F (on ENST00000487099 / NM_033334.4; = p.I58F on NM_001489.5) | Missense Mutation (SNP) | VAF 127/289 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60635659; called by muse, mutect2, varscan2
- NSG2 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 187/195 reads (96%) | SIFT tolerated (0.4); PolyPhen benign (0.175); catalogued as COSV100292956; called by muse, mutect2, varscan2
- NTNG1 | c.1286A>C p.H429P | Missense Mutation (SNP) | VAF 128/493 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as COSV64276101; called by muse, mutect2, varscan2
- OR10J1 | c.325A>T p.I109F | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV71129247; called by muse, mutect2, varscan2
- OR5AN1 | c.310A>T p.I104F | Missense Mutation (SNP) | VAF 118/524 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.319); catalogued as COSV58322499; called by muse, mutect2, varscan2
- OR5H2 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 70/558 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs769324469, COSV100788878, COSV62351407; called by muse, mutect2, varscan2
- PRDM7 | c.1079A>G p.E360G | Missense Mutation (SNP) | VAF 97/365 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV57987427; called by muse, mutect2, varscan2
- PTPRK | c.3740C>A p.T1247K (on ENST00000368215 / NM_001291984.2; = p.T1248K on NM_002844.4) | Missense Mutation (SNP) | VAF 75/488 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63903188; called by muse, mutect2, varscan2
- RABEP2 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 45/224 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753049047, COSV62868850; called by muse, mutect2, varscan2
- RDH13 | c.861C>G p.Y287* (on ENST00000415061 / NM_001145971.2; = p.Y216* on NM_138412.4) | Nonsense Mutation (SNP) | VAF 35/140 reads (25%) | catalogued as rs757565961, COSV52561953; called by muse, mutect2, varscan2
- RFTN1 | c.1342C>T p.R448* | Nonsense Mutation (SNP) | VAF 65/67 reads (97%) | catalogued as rs754652628, COSV61918069; called by muse, mutect2, varscan2
- RFX3 | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 73/511 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs370801268; called by muse, mutect2, varscan2
- SCN11A | c.2000C>A p.P667Q | Missense Mutation (SNP) | VAF 107/290 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV100182711; called by muse, mutect2, varscan2
- SEC24C | c.1760T>C p.F587S | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100227183; called by muse, mutect2
- SGO2 | c.3318G>T p.K1106N | Missense Mutation (SNP) | VAF 107/390 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.211); catalogued as COSV63416516; called by muse, mutect2, varscan2
- SLC22A10 | c.241T>A p.S81T | Missense Mutation (SNP) | VAF 410/557 reads (74%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV60422722; called by muse, mutect2, varscan2
- SLC25A48 | c.152G>T p.R51M | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV99192249; called by muse, mutect2, varscan2
- SMU1 | c.26+1G>A p.X9_splice | Splice Site (SNP) | VAF 78/277 reads (28%) | catalogued as COSV68140154; called by muse, mutect2, varscan2
- SUSD6 | c.359C>A p.S120Y | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61366094; called by muse, mutect2, varscan2
- SYNE2 | c.7808T>C p.L2603P | Missense Mutation (SNP) | VAF 127/285 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV59960460; called by muse, mutect2, varscan2
- TARS1 | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as COSV54310994; called by muse, mutect2, varscan2
- TGS1 | c.2177C>G p.A726G | Missense Mutation (SNP) | VAF 67/406 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV52701934; called by muse, mutect2, varscan2
- TMC7 | c.1459T>A p.W487R | Missense Mutation (SNP) | VAF 259/582 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV58585729; called by muse, mutect2, varscan2
- TMEM53 | c.400C>A p.R134S | Missense Mutation (SNP) | VAF 109/173 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV62408153; called by muse, mutect2, varscan2
- TNS1 | c.4538A>G p.Q1513R | Missense Mutation (SNP) | VAF 109/291 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as rs1380677122, COSV50733191; called by muse, mutect2, varscan2
- TRIM10 | c.1418G>A p.R473Q | Missense Mutation (SNP) | VAF 84/570 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.827); catalogued as COSV64998927; called by muse, mutect2, varscan2
- TTN | c.78001T>C p.Y26001H (on ENST00000591111; = p.Y18577H on NM_003319.4) | Missense Mutation (SNP) | VAF 318/854 reads (37%) | PolyPhen probably damaging (0.998); catalogued as COSV59981717, COSV60212781; called by muse, mutect2, varscan2
- UGT1A8 | c.233C>G p.S78* | Nonsense Mutation (SNP) | VAF 362/1285 reads (28%) | catalogued as rs200115254, COSV65082712; called by muse, mutect2, varscan2
- UNC119 | c.593dup p.L199Sfs*15 | Frame Shift Ins (INS) | VAF 7/42 reads (17%) | catalogued as rs762519155; called by mutect2, pindel, varscan2
- UTRN | c.2161A>G p.M721V | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV62342048; called by muse, mutect2, varscan2
- VARS2 | c.2261G>T p.R754L | Missense Mutation (SNP) | VAF 271/781 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV58913691, COSV58914684; called by muse, mutect2, varscan2
- ZBED1 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as rs771759980, COSV100586124; called by muse, mutect2, varscan2
- ZCCHC4 | c.499A>C p.K167Q | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV57182461; called by muse, mutect2, varscan2
- ZNF135 | c.883G>A p.E295K (on ENST00000313434 / NM_001289401.2; = p.E307K on NM_003436.4) | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs1212991134, COSV100536368, COSV100536935; called by muse, mutect2, varscan2
- ZNF235 | c.1673T>A p.L558H | Missense Mutation (SNP) | VAF 153/524 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52157605; called by muse, mutect2, varscan2
- ZNF365 | c.304T>C p.Y102H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV67925959; called by muse, mutect2, varscan2
- ZNF777 | c.1805G>T p.C602F | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV56099145; called by muse, mutect2, varscan2
- BVES | c.465_479delinsT p.L155Ffs*7 | Frame Shift Del (DEL) | VAF 48/301 reads (16%) | called by pindel, varscan2*
- CA1 | c.357del p.H120Tfs*2 | Frame Shift Del (DEL) | VAF 156/431 reads (36%) | called by mutect2, pindel, varscan2
- CCDC158 | c.2280_2286+9del p.X760_splice | Splice Site (DEL) | VAF 129/339 reads (38%) | called by mutect2, pindel, varscan2
- FBXO10 | c.959C>G p.T320S | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FZD6 | c.431_439del p.L144_P146del | In Frame Del (DEL) | VAF 46/283 reads (16%) | called by mutect2, pindel, varscan2
- IGHV1-46 | c.213C>G p.N71K | Missense Mutation (SNP) | VAF 22/405 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.095); called by muse, mutect2
- MRPL4 | c.915_921del p.A306Rfs*11 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | called by mutect2, varscan2
- MYO1F | c.679C>A p.L227I | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- PCBP2 | c.70_80del p.X24_splice | Splice Site (DEL) | VAF 16/88 reads (18%) | called by mutect2, pindel, varscan2
- PRR11 | c.185_201del p.W62* | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | called by mutect2, pindel, varscan2
- SELENOP | c.780_796del p.N260Kfs*? | Frame Shift Del (DEL) | VAF 51/174 reads (29%) | called by mutect2, pindel, varscan2
- TENM1 | c.5932_5954delinsT p.L1978Sfs*6 | Frame Shift Del (DEL) | VAF 87/377 reads (23%) | called by pindel, varscan2*
- THEMIS | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 22/490 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); called by muse, mutect2
- TOP2A | c.611_614dup p.E205Dfs*19 | Frame Shift Ins (INS) | VAF 220/2218 reads (10%) | called by pindel, varscan2
- TPTE2 | c.279_300del p.D94Nfs*13 (on ENST00000400230 / NM_199254.2; = p.D57Nfs*13 on NM_130785.3) | Frame Shift Del (DEL) | VAF 17/74 reads (23%) | called by mutect2, pindel, varscan2
- TRANK1 | c.6308_6353del p.N2103Tfs*3 | Frame Shift Del (DEL) | VAF 28/118 reads (24%) | called by mutect2, pindel
- ADGRA2 | c.2607C>G p.P869= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV55104707; called by muse, mutect2
- ALAS2 | c.1026G>A p.E342= | Silent (SNP) | VAF 94/390 reads (24%) | catalogued as COSV58192245; called by muse, mutect2, varscan2
- ARAP2 | c.135G>A p.L45= | Silent (SNP) | VAF 95/194 reads (49%) | catalogued as COSV58289767; called by muse, mutect2, varscan2
- CACNG7 | c.732C>T p.S244= | Silent (SNP) | VAF 108/320 reads (34%) | catalogued as COSV55816050; called by muse, mutect2, varscan2
- DIP2C | c.1440C>G p.P480= | Silent (SNP) | VAF 827/2302 reads (36%) | catalogued as COSV55169526; called by muse, mutect2, varscan2
- DOCK2 | c.2214G>A p.K738= | Silent (SNP) | VAF 26/662 reads (4%) | catalogued as COSV56959566; called by muse, mutect2
- EHHADH | c.1440G>C p.V480= | Silent (SNP) | VAF 103/633 reads (16%) | catalogued as COSV51631867; called by muse, mutect2, varscan2
- FBXO46 | c.1509C>T p.F503= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV58348558; called by muse, mutect2, varscan2
- FCGBP | c.6939C>T p.Y2313= | Silent (SNP) | VAF 17/248 reads (7%) | catalogued as rs574260833; called by muse, mutect2
- FGFR4 | c.1341C>G p.A447= | Silent (SNP) | VAF 259/461 reads (56%) | catalogued as COSV52805573, COSV99451030; called by muse, mutect2, varscan2
- FRS3 | c.693A>C p.P231= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV99443213; called by muse, varscan2
- KRTAP19-1 | c.183C>T p.G61= | Silent (SNP) | VAF 310/1131 reads (27%) | catalogued as COSV101185881; called by muse, mutect2, varscan2
- LILRB1 | c.351C>A p.G117= (on ENST00000427581; = p.G81= on NM_006669.6) | Silent (SNP) | VAF 96/472 reads (20%) | catalogued as rs755301934; called by muse, mutect2
- LRRC52 | c.30G>T p.G10= | Silent (SNP) | VAF 93/326 reads (29%) | catalogued as COSV54233017; called by muse, mutect2, varscan2
- MASP1 | c.720G>T p.V240= | Silent (SNP) | VAF 95/589 reads (16%) | catalogued as rs772872650, COSV51462151; called by muse, mutect2, varscan2
- MEGF8 | c.654G>A p.V218= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV52094208; called by muse, mutect2, varscan2
- PGLYRP1 | c.590G>A p.*197= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV50517240; called by muse, mutect2, varscan2
- PNMA5 | c.423A>G p.Q141= | Silent (SNP) | VAF 208/397 reads (52%) | catalogued as COSV62625966; called by muse, mutect2, varscan2
- PTK2B | c.2310G>T p.R770= | Silent (SNP) | VAF 101/350 reads (29%) | catalogued as COSV57761574; called by muse, mutect2, varscan2
- RIMS1 | c.5037A>G p.S1679= | Silent (SNP) | VAF 113/513 reads (22%) | catalogued as COSV99330844; called by muse, mutect2, varscan2
- SCN11A | c.2001A>T p.P667= | Silent (SNP) | VAF 107/294 reads (36%) | catalogued as COSV100182708; called by muse, mutect2, varscan2
- SLC9B1 | c.363T>C p.P121= | Silent (SNP) | VAF 34/140 reads (24%) | catalogued as COSV56468938, COSV56473183; called by muse, mutect2, varscan2
- SLCO2A1 | c.1785C>G p.A595= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as COSV60487665; called by muse, mutect2, varscan2
- SLITRK5 | c.2775A>G p.V925= | Silent (SNP) | VAF 59/105 reads (56%) | catalogued as COSV61524694; called by muse, mutect2, varscan2
- SVIL | c.5538T>C p.V1846= (on ENST00000355867 / NM_021738.3; = p.V1420= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2
- TFEB | c.642G>C p.A214= | Silent (SNP) | VAF 53/209 reads (25%) | catalogued as COSV57824856, COSV57825852; called by muse, mutect2, varscan2
- TLR5 | c.1404C>A p.T468= | Silent (SNP) | VAF 27/138 reads (20%) | catalogued as COSV60559947, COSV60560249; called by muse, mutect2, varscan2
- TPTE2 | c.465T>C p.D155= | Silent (SNP) | VAF 75/151 reads (50%) | catalogued as COSV55025367; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73851073 T>A | 3'Flank (SNP) | VAF 48/171 reads (28%) | catalogued as rs773740184; called by muse, mutect2, varscan2
- RPL23AP42 | n.195T>A | RNA (SNP) | VAF 56/522 reads (11%) | called by muse, mutect2, varscan2
- RREB1 | c.3809-5942A>G | Intron (SNP) | VAF 46/95 reads (48%) | catalogued as COSV58561825; called by muse, mutect2, varscan2
- SUCO | chr1:172532594 G>C | 5'Flank (SNP) | VAF 14/54 reads (26%) | catalogued as COSV99743950; called by muse, mutect2, varscan2
